Somatic mutation profile of tumor specimen MP2PRT-PAPGWN-TMP1-A (aliquot MP2PRT-PAPGWN-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPGWN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,830 days).
Specimen MP2PRT-PAPGWN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e03b0866-cabd-457f-8e9b-1980fae55ccf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGWN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGWN-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d852c373-818e-4276-a635-60ae343bc79d

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 99/498 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C12orf43 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 86/494 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs755288501, COSV56568245; called by muse, mutect2, varscan2
- CDSN | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 340/832 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CD118951; called by muse, varscan2
- COBL | c.3737G>A p.R1246H | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768711313, COSV54344749; called by muse, mutect2, varscan2
- DNAH2 | c.10382G>A p.R3461Q | Missense Mutation (SNP) | VAF 146/392 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs375708908; called by muse, mutect2, varscan2
- FBLN1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 142/389 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17852050, COSV99411550; called by muse, mutect2, varscan2
- GRM1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 106/450 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV51154276; called by muse, mutect2, varscan2
- IL21R | c.1549dup p.R517Pfs*48 | Frame Shift Ins (INS) | VAF 252/630 reads (40%) | catalogued as rs748992699; called by mutect2, varscan2
- KY | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs754383672, COSV101415010; called by muse, mutect2
- MAT1A | c.90G>A p.P30= | Splice Region (SNP) | VAF 27/259 reads (10%) | catalogued as rs757610779; called by muse, varscan2
- MXRA5 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 91/671 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54226273; called by muse, mutect2, varscan2
- SASH1 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 226/616 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs750280402, COSV66561339, COSV66561724; called by muse, mutect2, varscan2
- SORCS2 | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 73/548 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1371818196; called by muse, mutect2, varscan2
- TADA2A | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs367602386; called by muse, mutect2, varscan2
- FMO2 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 152/378 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF139 | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 21/529 reads (4%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.088); called by muse, mutect2
- SI | c.4160A>C p.K1387T | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLITRK1 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 184/462 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TEDC2 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 92/734 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMN2 | c.939G>A p.A313= | Silent (SNP) | VAF 360/957 reads (38%) | catalogued as rs1397777846; called by muse, mutect2, varscan2
- HYDIN | c.7863G>A p.P2621= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs573398504, COSV99992599; called by mutect2, varscan2
- NTS | c.486A>T p.I162= | Silent (SNP) | VAF 140/324 reads (43%) | called by muse, mutect2, varscan2
- SBK1 | c.159C>T p.Y53= | Silent (SNP) | VAF 217/540 reads (40%) | catalogued as rs747755798; called by muse, mutect2, varscan2
- ZNF296 | c.1362C>T p.F454= | Silent (SNP) | VAF 286/708 reads (40%) | catalogued as rs776455930, COSV55519476; called by muse, mutect2, varscan2
